Somatic mutation profile of tumor specimen TCGA-AJ-A3OJ-01A (aliquot TCGA-AJ-A3OJ-01A-11D-A228-09) from TCGA case TCGA-AJ-A3OJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 54.3 years (19,826 days).
Specimen TCGA-AJ-A3OJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54c68339-731d-4947-80b0-46511fbf870a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3OJ-10A (Blood Derived Normal), aliquot TCGA-AJ-A3OJ-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/857f3c70-5212-4f18-b3eb-801c98ef5e72

The open-access MAF lists 1,070 somatic variants for this specimen: 808 protein-altering or splice-affecting, 234 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 527, Silent 234, Frame Shift Del 186, Nonsense Mutation 35, Frame Shift Ins 32, Intron 15, In Frame Del 13, Splice Site 11, 3'Flank 6, 3'UTR 5, Splice Region 2, RNA 2.

Variants (750 of 1,070; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1064796660, CM1513387, COSV61533890; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248104, COSV99031563; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- LTBP4 | c.4238dup p.R1414Afs*27 (on ENST00000308370 / NM_001042544.1; = p.R1377Afs*27 on NM_003573.2) | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | catalogued as rs606231161; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYL2 | c.431del p.P144Lfs*3 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs786205430, CD130651; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDK3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs397515323, CM132388, COSV64792933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PMPCB | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200188353; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 31/73 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as rs377767326, CM064283, COSV61684940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WFS1 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs146670741; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763757370, COSV99933658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs187071406, COSV64679339; called by muse, mutect2, varscan2
- ABCC5 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV99657254; called by muse, mutect2, varscan2
- ABCG8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs766212636, CM012312, COSV55390446, COSV55393699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABTB1 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1477881757, COSV99230015; called by muse, mutect2, varscan2
- ACD | c.661G>C p.V221L (on ENST00000620338; = p.V132L on NM_022914.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as COSV99537904; called by muse, mutect2, varscan2
- ACKR3 | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99799715; called by muse, mutect2, varscan2
- ACSS2 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99404534; called by muse, mutect2, varscan2
- ACTA2 | c.686T>C p.M229T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.407); catalogued as rs1233607183, COSV99827193; called by muse, mutect2, varscan2
- ACTL6B | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs557777299, COSV99355677; called by muse, mutect2, varscan2
- ACTL8 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV100958701, COSV100958734, COSV100958806; called by muse, mutect2, varscan2
- ACTN4 | c.2619del p.D874Tfs*44 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 64/88 reads (73%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.1865del p.N622Ifs*71 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs750058585; called by mutect2, varscan2
- ADAMTS17 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs375653443; called by muse, mutect2, varscan2
- ADCY3 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV99568791; called by muse, mutect2, varscan2
- ADCY5 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1221027778, COSV59196136; called by muse, mutect2, varscan2
- ADGRB3 | c.2731T>C p.S911P | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99486257; called by muse, mutect2, varscan2
- ADGRE2 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100216300; called by muse, mutect2, varscan2
- ADGRG2 | c.1576C>A p.L526M (on ENST00000379869 / NM_001079858.3; = p.L523M on NM_005756.4) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100492455; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs761350619; called by mutect2, varscan2
- ADPRHL1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372476440; called by muse, mutect2, varscan2
- ADRA1D | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs140631465; called by muse, mutect2, varscan2
- ADSS1 | c.197del p.X66_splice | Splice Site (DEL) | VAF 18/60 reads (30%) | catalogued as rs760706338; called by mutect2, varscan2
- AEBP1 | c.2259_2261del p.K753del | In Frame Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs780700423; called by pindel, varscan2
- AGAP1 | c.2269C>T p.R757W (on ENST00000304032 / NM_001037131.3; = p.R704W on NM_014914.5) | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs988946656, COSV100366379; called by muse, mutect2, varscan2
- AGO2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV55046708; called by muse, mutect2
- AKAP13 | c.5699C>T p.S1900L (on ENST00000394518 / NM_007200.5; = p.S1904L on NM_006738.6) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs371321602; called by muse, mutect2, varscan2
- AKAP13 | c.6685C>T p.R2229W (on ENST00000394518 / NM_007200.5; = p.R2233W on NM_006738.6) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199748104; called by muse, mutect2, varscan2
- AKNA | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs756152244, COSV99800774; called by muse, mutect2, varscan2
- AL592490.1 | c.2219C>A p.P740H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101308246; called by muse, mutect2, varscan2
- ALDH3B1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99141998; called by muse, varscan2
- ANGPTL4 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as rs774924877, COSV100035020; called by muse, varscan2
- ANK3 | c.9620C>T p.S3207L | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as COSV99781331; called by muse, mutect2, varscan2
- ANKRD27 | c.1768T>C p.S590P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100043020; called by muse, mutect2, varscan2
- ANKRD28 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs762410032, COSV101080763; called by mutect2, varscan2
- ANKRD33 | c.145C>A p.L49M (on ENST00000340970 / NM_001304459.2; = p.L184M on NM_182608.4) | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001423; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 42/113 reads (37%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AP002748.5 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100568083; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs749401724; called by mutect2, varscan2
- ARFGEF3 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs1188172160, COSV52458645; called by muse, mutect2, varscan2
- ARHGEF17 | c.2150C>A p.S717Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.133); catalogued as COSV99736282; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID1A | c.6707G>C p.R2236P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV61379307; called by muse, mutect2, varscan2
- ARMC4 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1298639189, COSV99518863; called by muse, mutect2, varscan2
- ARRB2 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV99347164; called by muse, mutect2, varscan2
- ARSL | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs756191732, COSV66964952, COSV66965711, COSV66965923; called by muse, mutect2, varscan2
- ASAP2 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs75701656, COSV55628076, COSV55632262; called by muse, mutect2, varscan2
- ASMTL | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.718); catalogued as rs199829721, COSV67244780; called by muse, mutect2, varscan2
- ASXL2 | c.182A>G p.H61R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99711712; called by muse, mutect2, varscan2
- ATAD2 | c.4030dup p.S1344Kfs*28 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs775812316; called by mutect2, varscan2
- ATAD3A | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100186475; called by muse, mutect2, varscan2
- ATAD5 | c.1373del p.N458Mfs*14 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs1256945229; called by mutect2, varscan2
- ATG9A | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1381980139, COSV99522066; called by muse, mutect2, varscan2
- ATP2C2 | c.1733dup p.R579Efs*132 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs771595842; called by mutect2, pindel, varscan2
- BACH1 | c.2066A>G p.E689G | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1327558786, COSV99728508; called by muse, mutect2, varscan2
- BAP1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1312611941, COSV56234695; called by muse, mutect2, varscan2
- BARHL2 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.462); catalogued as rs545301985, COSV100966072; called by muse, mutect2, varscan2
- BBOF1 | c.405del p.A136Pfs*6 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1456367734; called by pindel, varscan2
- BCL9L | c.176A>C p.H59P | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100600069; called by muse, mutect2, varscan2
- BEST2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443670092, COSV99244575; called by muse, mutect2, varscan2
- BICD2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772514098, COSV100794214; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 9/14 reads (64%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.72); catalogued as rs146877980, COSV57204685, COSV99909651; called by muse, mutect2, varscan2
- BNIP3 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs745677503, COSV100893226; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs746043904; called by mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 29/100 reads (29%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C16orf90 | c.551G>A p.R184H (on ENST00000399645 / NM_001353385.2; = p.R175H on NM_001080524.2) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.067); catalogued as rs371199813; called by muse, mutect2, varscan2
- C19orf12 | c.210del p.L71Cfs*2 (on ENST00000392278 / NM_001031726.3; = p.L60Cfs*2 on NM_031448.6) | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs770374870; called by mutect2, pindel, varscan2
- C19orf57 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs750616610, COSV100694781; called by muse, mutect2, varscan2
- C1QC | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV101009509; called by muse, varscan2
- C1QL3 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100127044; called by muse, mutect2, varscan2
- C1orf52 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99641061; called by muse, mutect2, varscan2
- C1orf94 | c.1012T>C p.W338R (on ENST00000488417 / NM_001134734.2; = p.W148R on NM_032884.5) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100975114; called by muse, mutect2, varscan2
- CA11 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV50032701, COSV99320762; called by muse, mutect2, varscan2
- CACHD1 | c.3704dup p.Q1236Sfs*23 | Frame Shift Ins (INS) | VAF 23/42 reads (55%) | catalogued as rs764948820; called by mutect2, varscan2
- CAPN15 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs776415726, COSV54834153; called by muse, mutect2, varscan2
- CASZ1 | c.3917G>A p.G1306D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV59739151; called by muse, mutect2, varscan2
- CATSPER3 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs779616768, COSV99253993; called by muse, mutect2, varscan2
- CATSPERD | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs201522895, COSV100486921; called by muse, mutect2, varscan2
- CBX6 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99328219; called by muse, mutect2, varscan2
- CBY2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100137738; called by muse, mutect2, varscan2
- CCAR2 | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57905820; called by muse, mutect2, varscan2
- CCDC106 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as COSV100454376; called by muse, mutect2, varscan2
- CCDC159 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV100712296; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC68 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100491925; called by muse, mutect2, varscan2
- CCDC71 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs918183468, COSV100422403; called by muse, varscan2
- CCDC71 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.306); catalogued as COSV100422404; called by muse, varscan2
- CCDC9 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs201519530; called by muse, mutect2, varscan2
- CCL25 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99495221; called by muse, mutect2, varscan2
- CCM2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs374626897; called by muse, mutect2, varscan2
- CCN2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); catalogued as COSV100915342; called by muse, mutect2, varscan2
- CCR1 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99946667; called by muse, mutect2, varscan2
- CD3G | c.265G>T p.G89* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99416823; called by muse, varscan2
- CD63 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99141839; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH15 | c.2027C>T p.T676I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.144); catalogued as COSV99228651; called by muse, mutect2
- CDH23 | c.4054G>A p.A1352T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs773262846, COSV99822661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH9 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as rs150128137, COSV99142617; called by muse, mutect2, varscan2
- CDK11B | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 52/145 reads (36%) | catalogued as rs1287801341, COSV100478024; called by muse, mutect2, varscan2
- CDO1 | c.170G>T p.R57M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99164805; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs759091263; called by mutect2, varscan2
- CEACAM16 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs763317239, COSV69187372; called by muse, mutect2, varscan2
- CEACAM8 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.043); catalogued as COSV99747739; called by muse, mutect2, varscan2
- CELA3B | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs746930207, COSV100448833; called by muse, mutect2, varscan2
- CENPP | c.519del p.F173Lfs*46 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as rs750494120; called by mutect2, pindel, varscan2
- CEP128 | c.2201G>T p.R734M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV99825461; called by muse, mutect2, varscan2
- CEP89 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs778046770, COSV99993803; called by muse, mutect2, varscan2
- CFAP65 | c.4174G>T p.G1392* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100445560; called by muse, mutect2, varscan2
- CHAD | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs780934781, COSV99366268; called by muse, mutect2, varscan2
- CHD2 | c.3382G>A p.V1128M | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs776091604, COSV67711048; called by muse, mutect2, varscan2
- CHD4 | c.3425A>G p.Q1142R (on ENST00000357008 / NM_001363606.2; = p.Q1155R on NM_001273.5) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100538625; called by muse, mutect2, varscan2
- CHD6 | c.3774-1G>T p.X1258_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100498526; called by muse, mutect2, varscan2
- CHD6 | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777147193, COSV58563657; called by muse, mutect2, varscan2
- CHD7 | c.7767G>T p.K2589N | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101418353; called by muse, mutect2, varscan2
- CHERP | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199553205, COSV99550409; called by muse, mutect2, varscan2
- CHMP2A | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs773474943, COSV53396784; called by muse, mutect2, varscan2
- CHTF8 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54709325; called by muse, mutect2, varscan2
- CIART | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99290375; called by muse, mutect2, varscan2
- CLCA2 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199543422, COSV65287590; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLIP2 | c.2813A>G p.E938G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56284362; called by muse, mutect2, varscan2
- CLIP3 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1023578298, COSV53324559; called by muse, mutect2, varscan2
- CLIP4 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100192195; called by muse, mutect2, varscan2
- CLK3 | c.1456C>T p.R486C (on ENST00000395066 / NM_001130028.1; = p.R338C on NM_003992.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100166091, COSV59339986; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs369752219; called by mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs758676375; called by mutect2, varscan2
- COL12A1 | c.8990G>A p.R2997Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.248); catalogued as rs778638053, COSV59404120; called by muse, mutect2, varscan2
- COL6A6 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs774730504, COSV62039022; called by muse, mutect2, varscan2
- COL8A1 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766014652, COSV53737039; called by muse, mutect2, varscan2
- COL9A3 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs774501281, COSV58983459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COP1 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100443666; called by muse, mutect2, varscan2
- COQ6 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371260604, COSV99474165; called by muse, mutect2, varscan2
- CPVL | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99606214; called by muse, mutect2, varscan2
- CRACD | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as rs1453290454, COSV99949708; called by muse, mutect2, varscan2
- CRNKL1 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV101057075; called by muse, mutect2, varscan2
- CRYZ | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs754945572, COSV100558659; called by muse, mutect2, varscan2
- CSPG4 | c.3056C>A p.P1019H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100413951; called by muse, mutect2, varscan2
- CTCF | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs1567616147, COSV50500730; called by muse, mutect2, varscan2
- CTNND2 | c.3215G>A p.S1072N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as COSV100479322; called by muse, mutect2, varscan2
- CTSF | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs765918622, COSV59747264; called by muse, mutect2, varscan2
- CUX2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99920278; called by muse, mutect2, varscan2
- CXCR2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as rs373547007; called by muse, mutect2, varscan2
- CYB561A3 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99582568; called by muse, mutect2, varscan2
- CYBA | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs776963412, COSV55369074; called by muse, mutect2, varscan2
- CYBC1 | c.277_278del p.F93Qfs*13 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs1252279716; called by mutect2, pindel, varscan2
- CYFIP2 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as rs772567936, COSV100557488; called by muse, mutect2, varscan2
- CYP11B1 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52826608, COSV99455455; called by muse, mutect2, varscan2
- CYP3A4 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100315786; called by muse, mutect2, varscan2
- CYP4F22 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs116743462, COSV54106603; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs751187768; called by mutect2, varscan2
- DAG1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.644); catalogued as rs759876636, COSV100445074; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs779681511; called by mutect2, varscan2
- DCAF4L2 | c.683T>C p.L228S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100151121; called by muse, mutect2, varscan2
- DCAF5 | c.443T>C p.L148S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432686; called by muse, mutect2, varscan2
- DCST1 | c.1787A>G p.N596S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99665174; called by muse, mutect2, varscan2
- DCTN1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as rs752399708, COSV100721010; called by muse, mutect2, varscan2
- DCUN1D3 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1339285105, COSV60954587; called by muse, mutect2
- DDR1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100241866; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX51 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs544795955, COSV100223134; called by muse, mutect2, varscan2
- DDX6 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782274778, COSV99870550; called by muse, mutect2, varscan2
- DEF6 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs768719749, COSV100359452; called by muse, mutect2, varscan2
- DENND4B | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.948); catalogued as rs1478939439, COSV100768812; called by muse, mutect2, varscan2
- DGAT2L6 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778176074, COSV60717131; called by muse, mutect2, varscan2
- DGCR8 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV61227958; called by muse, mutect2, varscan2
- DGKB | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV51804089, COSV99341780; called by muse, mutect2, varscan2
- DGKK | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV101053136; called by muse, mutect2
- DHX34 | c.3124G>A p.A1042T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs148368794; called by muse, mutect2, varscan2
- DLC1 | c.2537C>A p.P846H (on ENST00000276297 / NM_001348081.2; = p.P409H on NM_006094.5) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52313237; called by muse, mutect2, varscan2
- DLGAP4 | c.2813C>T p.P938L (on ENST00000339266 / NM_001365621.1; = p.P935L on NM_014902.6) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs753107733, COSV100211467; called by muse, mutect2, varscan2
- DLL1 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100816151; called by muse, mutect2, varscan2
- DNA2 | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622701; called by muse, mutect2, varscan2
- DNA2 | c.1348C>A p.L450M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100622704; called by muse, mutect2, varscan2
- DNAH1 | c.7759G>A p.V2587M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.907); catalogued as rs747611842, COSV70225891; called by muse, mutect2, varscan2
- DNAH2 | c.1463G>A p.G488D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1373893406, COSV99318385; called by muse, mutect2, varscan2
- DNAH9 | c.5656G>A p.A1886T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1309622977, COSV52334000; called by muse, mutect2, varscan2
- DNAI2 | c.1073G>A p.C358Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV100209954; called by muse, mutect2, varscan2
- DNMT3A | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1468255229, COSV99258616, COSV99262738; called by muse, mutect2, varscan2
- DOCK2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139449745; called by muse, mutect2, varscan2
- DPEP3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1309765137, COSV99262815; called by muse, mutect2
- DRGX | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV100938368; called by muse, mutect2, varscan2
- DROSHA | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868625207, COSV100757699; called by muse, mutect2, varscan2
- DSCAML1 | c.5944G>A p.V1982M (on ENST00000321322; = p.V1922M on NM_020693.4) | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs375677675; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs750962255; called by mutect2, varscan2
- DTX1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99986443; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs746928635; called by mutect2, varscan2
- DYNC1H1 | c.7586C>T p.A2529V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs746209887, COSV100795161; called by muse, mutect2, varscan2
- DZIP1L | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759170608, COSV100551594; called by muse, mutect2, varscan2
- EEF2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58579035; called by muse, mutect2, varscan2
- EGF | c.2693G>A p.R898Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs757524102, COSV54480110, COSV99491221; called by muse, mutect2, varscan2
- EGR1 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV53519250; called by muse, mutect2, varscan2
- EHD1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.856); catalogued as rs772683924, COSV57736528; called by muse, mutect2, varscan2
- EIF2A | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99856062; called by muse, mutect2, varscan2
- EIF2AK1 | c.668A>G p.H223R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99552146; called by muse, mutect2, varscan2
- ELAVL1 | c.400A>G p.N134D | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100688437; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs751148694; called by mutect2, varscan2
- ELP3 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as rs765496547, COSV99833808; called by muse, mutect2, varscan2
- EMG1 | c.182_183del p.Y61* | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs1555152684; called by pindel, varscan2
- ENPP2 | c.2035G>A p.G679R (on ENST00000075322 / NM_001040092.3; = p.G731R on NM_006209.5) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50015489; called by muse, mutect2, varscan2
- EPHA2 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs767460372, COSV100626224; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs756407271; called by mutect2, pindel, varscan2
- ERAS | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99504876; called by muse, mutect2, varscan2
- ERCC3 | c.1280T>C p.M427T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99573529; called by muse, mutect2, varscan2
- ERN1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV101458492; called by muse, mutect2, varscan2
- EXOC7 | c.1620C>G p.F540L (on ENST00000335146 / NM_001145297.4; = p.F458L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.13); catalogued as COSV100135541; called by muse, mutect2, varscan2
- EXOSC8 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99523761; called by muse, mutect2, varscan2
- EZH2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV57451724; called by muse, mutect2, varscan2
- F8 | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100811695; called by muse, mutect2, varscan2
- FADS1 | c.1492T>C p.Y498H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100650299; called by muse, mutect2, varscan2
- FAM50A | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99341125; called by muse, mutect2, varscan2
- FAM71D | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs201295116, COSV100315304; called by muse, mutect2, varscan2
- FAT4 | c.12379G>A p.V4127M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761178590, COSV100628654; called by muse, mutect2, varscan2
- FBN2 | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52526336; called by muse, mutect2, varscan2
- FEZF1 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs144474907, COSV100484465; called by muse, mutect2, varscan2
- FGD1 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100911211; called by muse, mutect2, varscan2
- FHL1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100600819; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLNC | c.3587C>T p.A1196V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV100368461; called by muse, mutect2, varscan2
- FLNC | c.4754C>A p.P1585H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100368464; called by muse, mutect2, varscan2
- FLRT2 | c.1610T>C p.M537T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100420753; called by muse, mutect2, varscan2
- FLYWCH1 | c.1964G>A p.S655N (on ENST00000253928 / NM_001308068.2; = p.S654N on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.396); catalogued as COSV99559072; called by muse, mutect2, varscan2
- FMNL2 | c.2501G>A p.S834N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99980291; called by muse, mutect2, varscan2
- FMO4 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs746984414, COSV100882114; called by muse, mutect2, varscan2
- FOSL2 | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99268453; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs760347049; called by pindel, varscan2
- FOXRED1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005419; called by muse, mutect2, varscan2
- FRMD3 | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as COSV100171008; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs752538869; called by mutect2, varscan2
- FRY | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs1227588645, COSV100969660; called by muse, mutect2, varscan2
- FRYL | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as rs756586585, COSV99977595; called by muse, mutect2, varscan2
- FSCB | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV100469633; called by muse, mutect2, varscan2
- GALNS | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs750739641, COSV51937355, COSV99243358; called by muse, mutect2, varscan2
- GATAD2A | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53068272; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | catalogued as rs548474277; called by mutect2, varscan2
- GCN1 | c.5092C>T p.P1698S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100325712; called by muse, mutect2
- GCN1 | c.2630T>C p.I877T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100325714; called by muse, mutect2, varscan2
- GGCX | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs750566705, COSV99290086; called by muse, mutect2, varscan2
- GHRHR | c.366+2T>C p.X122_splice | Splice Site (SNP) | VAF 43/115 reads (37%) | catalogued as COSV100396704; called by muse, mutect2, varscan2
- GIPC1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs745393596, COSV100600135; called by muse, varscan2
- GJD2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs202150693, COSV51747514; called by muse, mutect2, varscan2
- GK2 | c.388dup p.I130Nfs*5 | Frame Shift Ins (INS) | VAF 18/70 reads (26%) | catalogued as rs771628988; called by mutect2, varscan2
- GLI2 | c.2107C>T p.R703C (on ENST00000361492 / NM_001374353.1; = p.R720C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs773976966, COSV100083906; called by muse, mutect2, varscan2
- GLYCTK | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV59793773, COSV99980875; called by muse, mutect2, varscan2
- GNPTAB | c.1113+2T>C p.X371_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as COSV100172238; called by muse, mutect2, varscan2
- GORASP2 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99304664; called by muse, mutect2, varscan2
- GP5 | c.872del p.G291Afs*7 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs748422735; called by pindel, varscan2
- GPR137 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs1356099228, COSV100464398; called by muse, mutect2, varscan2
- GPR37 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs774806947, COSV58259643; called by muse, mutect2, varscan2
- GRIA4 | c.2624C>T p.T875M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs201725650, COSV56887848; called by muse, mutect2, varscan2
- GRXCR1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs200231391, COSV101295719, COSV67674982; called by muse, mutect2, varscan2
- GTF2IRD1 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV99735109; called by muse, mutect2, varscan2
- GUCY2D | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757387072, COSV99644169; ClinVar: uncertain significance; called by muse, varscan2
- GYS2 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767722149, COSV53928734; called by muse, mutect2, varscan2
- H4C12 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100694806; called by muse, mutect2, varscan2
- HAUS8 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); catalogued as rs141370009; called by muse, varscan2
- HCAR1 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100811691; called by muse, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HELZ | c.5402C>T p.P1801L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as rs538310655, COSV62379250; called by muse, mutect2, varscan2
- HIVEP1 | c.4957A>G p.T1653A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV101045448; called by muse, mutect2, varscan2
- HK3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99459008; called by muse, mutect2, varscan2
- HKDC1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs201010349, COSV100664698; called by muse, mutect2, varscan2
- HPD | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.17); catalogued as rs202129288, COSV100000180; called by muse, mutect2, varscan2
- HPN | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs145117053; called by muse, varscan2
- HS3ST3A1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV99404436; called by muse, mutect2, varscan2
- HS6ST2 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs201372916, COSV100896932, COSV100897298; called by muse, varscan2
- HTR1B | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64051949; called by muse, mutect2, varscan2
- HTRA1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as CM153334, COSV64564034; called by muse, mutect2, varscan2
- HUWE1 | c.6485G>A p.R2162Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53351330; called by muse, mutect2, varscan2
- HUWE1 | c.5867A>G p.Y1956C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99473433; called by muse, mutect2, varscan2
- ICE1 | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as rs758941095, COSV56832745; called by muse, mutect2, varscan2
- IFI16 | c.252del p.E85Kfs*3 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs1557862995; called by mutect2, pindel, varscan2
- IFRD2 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.6); catalogued as COSV100269696; called by muse, mutect2, varscan2
- IGHG4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs756452414; called by muse, mutect2, varscan2
- IGSF9B | c.3284T>C p.L1095P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100318133; called by muse, mutect2, varscan2
- IL21R | c.1513T>C p.C505R | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV100560355; called by muse, mutect2, varscan2
- IL31RA | c.751del p.M251Wfs*3 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs777899150; called by mutect2, pindel, varscan2
- ILKAP | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99611097; called by muse, mutect2, varscan2
- INTS1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV101248196; called by muse, mutect2, varscan2
- INTS10 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs760330011, COSV101208721; called by muse, mutect2, varscan2
- IQGAP1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs199859960, COSV51590616; called by muse, mutect2, varscan2
- ITGA7 | c.1775G>A p.R592H (on ENST00000555728; = p.R548H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs746596659, COSV57696580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IVD | c.1120G>A p.V374I (on ENST00000651168; = p.V371I on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV99991550; called by muse, mutect2, varscan2
- JAG2 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs140376952; called by muse, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as COSV52470301; called by mutect2, pindel, varscan2
- KCNH1 | c.1394G>C p.G465A (on ENST00000271751 / NM_172362.3; = p.G438A on NM_002238.4) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99660428; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | catalogued as COSV99236896; called by mutect2, pindel, varscan2
- KCNIP1 | c.284A>G p.H95R (on ENST00000411494 / NM_001034837.3; = p.H84R on NM_014592.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs767816503, COSV61082838; called by muse, mutect2, varscan2
- KCNJ5 | c.326G>T p.W109L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100610753, COSV57966287; called by muse, mutect2, varscan2
- KDM3B | c.4414C>T p.R1472* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as rs1561796122, COSV100069409, COSV58693606; called by muse, mutect2, varscan2
- KIAA1109 | c.13123C>T p.R4375* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs1366683564, COSV99168197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1841 | c.1938C>T p.D646= | Splice Region (SNP) | VAF 17/47 reads (36%) | catalogued as rs761990557, COSV54377967; called by muse, mutect2, varscan2
- KIF22 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV99361341; called by muse, mutect2, varscan2
- KIF5C | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101276179; called by muse, mutect2, varscan2
- KIRREL2 | c.1974G>T p.R658S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV99384231; called by muse, mutect2, varscan2
- KL | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.326); catalogued as rs753320325, COSV101199171; called by muse, mutect2, varscan2
- KLC3 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as rs760262930, COSV101228798; called by muse, mutect2, varscan2
- KLHL21 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs140427901; called by muse, mutect2, varscan2
- KLKB1 | c.418del p.R140Gfs*29 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as rs755680952; called by mutect2, pindel, varscan2
- KMT2B | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.964); catalogued as rs201967801; called by muse, mutect2, varscan2
- KRT74 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV99977606, COSV99977670; called by muse, mutect2, varscan2
- KRT8 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV99510212; called by muse, mutect2, varscan2
- LAMA3 | c.4063G>T p.G1355C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100557298; called by muse, mutect2, varscan2
- LETM1 | c.432del p.A145Qfs*5 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as rs745839823; called by mutect2, pindel, varscan2
- LETMD1 | c.115del p.A39Pfs*15 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1566076595; called by mutect2, varscan2
- LGI3 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs751236253, COSV100103206, COSV99073482; called by muse, mutect2, varscan2
- LILRB1 | c.1694G>T p.R565I (on ENST00000427581; = p.R515I on NM_006669.6) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100207594; called by muse, mutect2
- LILRB2 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV100079521; called by muse, mutect2, varscan2
- LIME1 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100203230; called by muse, mutect2, varscan2
- LIPG | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99724615; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMO7 | c.765del p.R256Vfs*58 (on ENST00000357063; = p.R271Vfs*58 on NM_005358.5) | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as COSV58538121; called by mutect2, pindel, varscan2
- LMOD3 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs199655993, COSV101342015; called by muse, mutect2, varscan2
- LPA | c.3287+1G>A p.X1096_splice | Splice Site (SNP) | VAF 97/286 reads (34%) | catalogued as rs767906902, COSV60309190; called by muse, mutect2, varscan2
- LPL | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100255710; called by muse, mutect2, varscan2
- LRBA | c.6038T>C p.V2013A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100841938; called by muse, mutect2, varscan2
- LRPAP1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs376919981; called by muse, mutect2, varscan2
- LRRC32 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs757556414, COSV52631689; called by muse, mutect2, varscan2
- LRRC56 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99530097; called by muse, mutect2, varscan2
- LRRTM1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99702898; called by muse, mutect2, varscan2
- LSP1 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV61136065; called by muse, mutect2
- LYPD4 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV100419455, COSV100419536; called by muse, mutect2, varscan2
- LYSMD1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754782146, COSV100925224; called by muse, mutect2, varscan2
- M1AP | c.933-2A>G p.X311_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99304349; called by muse, mutect2, varscan2
- MAB21L1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59822159; called by muse, mutect2, varscan2
- MAG | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1336057539, COSV100727976; called by muse, mutect2, varscan2
- MAGEA8 | c.296del p.P99Rfs*21 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as COSV54065036; called by mutect2, pindel, varscan2
- MAGED2 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1224065321, COSV99514679; called by muse, mutect2, varscan2
- MAK | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100504560; called by muse, mutect2, varscan2
- MAMLD1 | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99476379; called by muse, mutect2, varscan2
- MAP3K1 | c.1657T>C p.Y553H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV101267079; called by muse, mutect2, varscan2
- MAP3K1 | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV68124040; called by muse, mutect2, varscan2
- MAPK13 | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99275358; called by muse, mutect2, varscan2
- MARCHF9 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs576143911, COSV99874960; called by muse, mutect2, varscan2
- MASP2 | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as rs781121308, COSV99534385; called by muse, mutect2, varscan2
- MAST3 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs202117591, COSV99445882; called by muse, mutect2, varscan2
- MAST3 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373396984; called by muse, mutect2, varscan2
- MATR3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs138894013; called by muse, mutect2, varscan2
- MCM10 | c.2102del p.N701Tfs*35 (on ENST00000484800 / NM_182751.3; = p.N700Tfs*35 on NM_018518.5) | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs772561920; called by mutect2, pindel, varscan2
- MCM4 | c.2320A>G p.T774A | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs1163499757, COSV100031189; called by muse, mutect2, varscan2
- MED13 | c.5545G>T p.G1849* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV101181207; called by muse, mutect2, varscan2
- MED13L | c.2049G>A p.W683* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV99929594; called by muse, mutect2, varscan2
- MED14 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs1034557473, COSV61357885; called by muse, mutect2, varscan2
- MEF2B | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99364931; called by muse, mutect2, varscan2
- MEGF11 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as rs368136830; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs780635289; called by mutect2, varscan2
- MGA | c.7307G>A p.R2436H (on ENST00000219905 / NM_001164273.1; = p.R2227H on NM_001080541.2) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1054243525, COSV54949857; called by muse, mutect2, varscan2
- MGRN1 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs200497316, COSV99274581; called by muse, mutect2, varscan2
- MICALL2 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766085386, COSV99876143; called by muse, varscan2
- MINK1 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs202132377, COSV100767217; called by muse, varscan2
- MINK1 | c.3034C>T p.R1012W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53418103; called by muse, mutect2, varscan2
- MKI67 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs763124240, COSV100896846; called by muse, mutect2, varscan2
- MKRN1 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99751810; called by muse, mutect2
- MMAB | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs368584846, CM061123; called by muse, mutect2, varscan2
- MMP14 | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs757515188, COSV100314226; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs755830405; called by mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs753079987; called by mutect2, varscan2
- MRPL11 | c.251A>C p.Q84P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV100207816; called by muse, mutect2, varscan2
- MRTFA | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100844256; called by muse, mutect2, varscan2
- MS4A13 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100981156; called by muse, mutect2, varscan2
- MS4A2 | c.425del p.G142Efs*7 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as COSV54012718; called by mutect2, pindel, varscan2
- MSH3 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs372048303; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MSH6 | c.3264_3266del p.F1088del | In Frame Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs1060502917; called by pindel, varscan2
- MSL3 | c.1012C>T p.R338C (on ENST00000312196 / NM_078629.4; = p.R172C on NM_006800.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1275511560, COSV56493447; called by muse, mutect2, varscan2
- MST1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs756280399, COSV99610941; called by muse, mutect2, varscan2
- MST1R | c.931del p.A311Pfs*27 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | catalogued as rs760002850, CM153853; called by mutect2, pindel, varscan2
- MTG2 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100895184; called by muse, mutect2, varscan2
- MUC4 | c.14423C>T p.A4808V (on ENST00000463781 / NM_018406.7; = p.A572V on NM_004532.6) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100205655; called by muse, mutect2, varscan2
- MUC6 | c.7069_7071del p.E2357del | In Frame Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs766760246; called by pindel, varscan2
- MXRA5 | c.6407A>G p.Q2136R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99478275; called by muse, mutect2, varscan2
- MYBBP1A | c.1279A>G p.T427A | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV99626593; called by muse, mutect2, varscan2
- MYH14 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1270544217, COSV51819425, COSV99222586; called by muse, mutect2, varscan2
- MYH4 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs774524623, COSV55124896; called by muse, mutect2, varscan2
- MYH7B | c.3946C>T p.R1316W | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs766880642, COSV99328709; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO1C | c.1862C>T p.A621V (on ENST00000648651 / NM_001080779.2; = p.A586V on NM_033375.5) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs1272525513, COSV100704480; called by muse, mutect2, varscan2
- MYO1F | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs367568601; called by muse, mutect2, varscan2
- NANOG | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as COSV99981676; called by muse, mutect2, varscan2
- NAV2 | c.3046G>A p.D1016N (on ENST00000396087 / NM_001244963.2; = p.D993N on NM_145117.5) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100217382; called by muse, mutect2, varscan2
- NCAPD2 | c.1570C>A p.L524I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV100217339; called by muse, mutect2, varscan2
- NCOA6 | c.5108C>A p.P1703H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100750203; called by muse, mutect2, varscan2
- NCOA6 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs777888525, COSV100750204; called by muse, mutect2, varscan2
- NCOA7 | c.814A>G p.M272V | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs777587206, COSV57655634; called by muse, mutect2, varscan2
- NDST2 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs375290937; called by muse, mutect2, varscan2
- NDUFC2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778952861, COSV55247188; called by muse, mutect2, varscan2
- NEB | c.9193C>T p.H3065Y | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1369787156, COSV99425826; called by muse, mutect2, varscan2
- NEUROD6 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51770979; called by muse, mutect2, varscan2
- NLRC4 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100707469; called by muse, mutect2, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, varscan2
- NOL6 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs915065164, COSV99954985; called by muse, mutect2, varscan2
- NPAS1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451429; called by muse, mutect2, varscan2
- NRXN2 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs781592079, COSV55452536, COSV55463954; called by muse, mutect2, varscan2
- NSMAF | c.504+1G>A p.X168_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99233229; called by muse, mutect2, varscan2
- NTAN1 | c.890dup p.N297Kfs*2 | Frame Shift Ins (INS) | VAF 24/89 reads (27%) | catalogued as rs753931847; called by mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP58 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.234); catalogued as COSV101098857; called by muse, mutect2, varscan2
- OAF | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs11545299, COSV100202970; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs753966040; called by mutect2, varscan2
- OR10H2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs549916970, COSV59946004; called by muse, mutect2, varscan2
- OR11H6 | c.370del p.S124Hfs*31 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs762454146; called by mutect2, pindel, varscan2
- OR1L8 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100508620; called by muse, mutect2, varscan2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as rs749245232; called by mutect2, pindel, varscan2
- OR4C3 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100168103; called by muse, mutect2, varscan2
- OR52E2 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1181875179, COSV100384867; called by muse, mutect2, varscan2
- ORC4 | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.245); catalogued as COSV51575643, COSV99932395; called by muse, mutect2, varscan2
- OSBP2 | c.2200G>A p.V734M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1247969067, COSV100213490; called by muse, mutect2, varscan2
- OSBPL10 | c.875G>A p.C292Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101159701; called by muse, mutect2, varscan2
- OSBPL11 | c.925G>T p.G309* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV99954401; called by muse, mutect2, varscan2
- OSBPL2 | c.1380del p.D461Tfs*44 (on ENST00000313733 / NM_144498.4; = p.D449Tfs*44 on NM_014835.4) | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs1298433831; called by mutect2, pindel, varscan2
- OTUD4 | c.278G>A p.R93H (on ENST00000447906 / NM_001366057.1; = p.R28H on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.674); catalogued as rs747742018, COSV99669223; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as CD124838, COSV100258088; called by mutect2, varscan2
- PABPC3 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs374600584; called by muse, mutect2, varscan2
- PAFAH1B3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs549905897, COSV50562838; called by muse, mutect2, varscan2
- PAIP1 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs537292836, COSV100166680; called by muse, mutect2, varscan2
- PAK4 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571403056, COSV58944697; called by muse, varscan2
- PAK6 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99544798; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAN2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765974777, COSV99228403; called by muse, mutect2, varscan2
- PANK4 | c.72dup p.D25Rfs*50 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs768596064; called by mutect2, pindel
- PARP4 | c.3182T>A p.L1061H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101131868; called by muse, mutect2
- PAX5 | c.76del p.V26Ffs*3 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as COSV63906212; called by mutect2, pindel, varscan2
- PCARE | c.2966del p.P989Lfs*46 | Frame Shift Del (DEL) | VAF 36/109 reads (33%) | catalogued as rs770881706; called by mutect2, pindel, varscan2
- PCDH7 | c.2769del p.F923Lfs*204 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as COSV62340410; called by mutect2, pindel, varscan2
- PCDHGA10 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1382323701, COSV99542966; called by muse, mutect2, varscan2
- PCDHGA6 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as COSV99542963; called by muse, mutect2, varscan2
- PCF11 | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs759339014, COSV100018903; called by muse, mutect2, varscan2
- PCMTD2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759306579, COSV55059113; called by muse, mutect2, varscan2
- PCNX2 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs1392209488, COSV99268785; called by muse, mutect2, varscan2
- PDE6C | c.2501_2503del p.E834del | In Frame Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs757524417; called by pindel, varscan2
- PDE9A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1479153246, COSV99371010; called by muse, mutect2, varscan2
- PDZRN3 | c.2791C>T p.R931C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55194734, COSV55210091; called by muse, mutect2, varscan2
- PELI3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs143638418, COSV57858108; called by muse, mutect2, varscan2
- PELP1 | c.2866_2868del p.E956del | In Frame Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs1402963402; called by pindel, varscan2
- PEX6 | c.2915G>A p.R972H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs751058292, COSV55102482, COSV55104293; called by muse, mutect2, varscan2
- PFN4 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100500416; called by muse, mutect2
- PGAM5 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs200488875, COSV58202330; called by muse, mutect2, varscan2
- PHC2 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs766329171, COSV99931251; called by muse, mutect2, varscan2
- PHTF1 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776165740, COSV100760157; called by muse, mutect2, varscan2
- PIGO | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs753918558, COSV53056465; called by muse, mutect2, varscan2
- PIK3C2G | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143896492, COSV56840839; called by muse, varscan2
- PIK3CG | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs187257485, COSV63248186; called by muse, varscan2
- PLCG1 | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99719089; called by muse, mutect2, varscan2
- PLEKHG3 | c.2900G>A p.S967N (on ENST00000394691; = p.S1023N on NM_001308147.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99906877; called by muse, mutect2, varscan2
- PLEKHG4B | c.994G>A p.D332N (on ENST00000283426; = p.D688N on NM_052909.5) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as rs753020603, COSV52051168; called by muse, mutect2, varscan2
- PLG | c.1504T>C p.C502R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV99804942; called by muse, mutect2, varscan2
- PLOD3 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV56183856, COSV99778159; called by muse, mutect2, varscan2
- PLXNA1 | c.4675C>T p.R1559C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765698174, COSV52526484; called by muse, mutect2, varscan2
- PLXNA3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs781795304, COSV100860130; called by muse, mutect2, varscan2
- PLXNB3 | c.2625C>A p.S875R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100737694, COSV100738088, COSV62796646; called by muse, mutect2, varscan2
- PLXNC1 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.359); catalogued as rs777861319, COSV99313513; called by muse, mutect2, varscan2
- PNLDC1 | c.1224+1G>A p.X408_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as rs771497671, COSV51707699; called by muse, mutect2, varscan2
- PNPT1 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99570323; called by muse, mutect2, varscan2
- POLD1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373001984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR3GL | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs782207671, COSV100996850; called by muse, mutect2, varscan2
- POU3F3 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796872; called by muse, mutect2, varscan2
- PPARGC1B | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs777341582, COSV58525852; called by muse, mutect2, varscan2
- PPEF2 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs201749049, COSV54422501; called by muse, mutect2, varscan2
- PPIG | c.2042del p.K681Rfs*12 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs775130624; called by mutect2, varscan2
- PPL | c.4790G>A p.R1597Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs138228343, COSV52173679; called by muse, mutect2, varscan2
- PPM1H | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99956230; called by muse, mutect2, varscan2
- PPP1R13B | c.1531del p.Q511Sfs*39 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | catalogued as rs758922105; called by mutect2, pindel, varscan2
- PRDM2 | c.4859C>T p.A1620V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs762850235, COSV99342329; called by muse, varscan2
- PRKAG3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99292057; called by muse, mutect2, varscan2
- PRKD2 | c.2407A>G p.S803G | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.266); catalogued as rs1244118550, COSV99354497; called by muse, mutect2, varscan2
- PRR19 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.463); catalogued as rs146879926, COSV56627140; called by muse, mutect2, varscan2
- PRRT2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs147004110; ClinVar: uncertain significance; called by muse, varscan2
- PRSS3 | c.406G>A p.A136T (on ENST00000361005 / NM_007343.4; = p.A244T on NM_002771.3) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs147576552; called by muse, mutect2, varscan2
- PRSS36 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV99191304; called by muse, mutect2, varscan2
- PRTG | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs199840624; called by muse, mutect2, varscan2
- PSMC2 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as COSV99485404; called by muse, mutect2, varscan2
- PSMC3 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242700261, COSV100099689; called by muse, mutect2, varscan2
- PTGES2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs368606962, COSV99476419; called by muse, mutect2, varscan2
- PTGR1 | c.770del p.P257Qfs*28 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as COSV53030433, COSV99437253; called by mutect2, varscan2
- PTK7 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs548376759, COSV100030440; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPN23 | c.3514C>T p.R1172W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs772953426, COSV99650428; called by muse, varscan2
- PTPRE | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749301869, COSV99618512; called by muse, mutect2, varscan2
- PTX4 | c.926G>A p.R309H (on ENST00000447419 / NM_001328608.2; = p.R304H on NM_001013658.1) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1217053322, COSV99560680; called by muse, mutect2
- PYGL | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749811385, COSV99368901; called by muse, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs755727862; called by mutect2, varscan2
- RAB1B | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs1362931479, COSV100270828; called by muse, mutect2, varscan2
- RABGAP1L | c.2389C>T p.R797* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52293676; called by muse, mutect2, varscan2
- RAI14 | c.816dup p.R273Tfs*15 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs1355946206; called by mutect2, varscan2
- RAPSN | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs761584017, CM031721, COSV100100323; called by muse, mutect2, varscan2
- RASA3 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1183874832, COSV100480972; called by muse, mutect2, varscan2
- RASGRP4 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs374569775; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs751690893; called by mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs762006287; called by mutect2, varscan2
- RECQL5 | c.1415A>C p.E472A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.347); catalogued as COSV100512173; called by muse, varscan2
- RELA | c.1459del p.H487Tfs*7 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV58014427; called by mutect2, pindel, varscan2
- RETREG1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs749712805, COSV60452745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGL3 | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100993064; called by muse, mutect2, varscan2
- RHCG | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99174171; called by muse, mutect2, varscan2
- RHOBTB2 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99311151; called by muse, mutect2, varscan2
- RHPN2 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs753950362, COSV54279253; called by muse, mutect2, varscan2
- RIMS4 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); catalogued as COSV65719652; called by muse, mutect2, varscan2
- RINL | c.379G>A p.A127T (on ENST00000591812 / NM_001195833.2; = p.A13T on NM_198445.4) | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV100531277; called by muse, mutect2, varscan2
- RIOX1 | c.1121G>A p.S374N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100408075; called by muse, mutect2, varscan2
- RNF213 | c.13013G>A p.R4338H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60407456; called by muse, mutect2, varscan2
- RNPEPL1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99549636; called by muse, mutect2, varscan2
- ROCK2 | c.3484C>T p.R1162* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1163971067, COSV100255652; called by muse, mutect2, varscan2
- RP1L1 | c.2948C>T p.A983V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV101223453; called by muse, varscan2
- RPGRIP1L | c.2938A>G p.I980V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100046596; called by muse, mutect2, varscan2
- RPS6KA2 | c.1747C>A p.L583M | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99690474; called by muse, mutect2, varscan2
- RRBP1 | c.3913C>T p.Q1305* (on ENST00000377813 / NM_001365613.2; = p.Q872* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99854338; called by muse, mutect2, varscan2
- RTN4RL1 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs748509266, COSV100486703; called by muse, mutect2, varscan2
- RXFP2 | c.917A>T p.N306I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV100034458; called by muse, mutect2, varscan2
- RXRB | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1398113257, COSV100554332, COSV59494106; called by muse, mutect2, varscan2
- RYR2 | c.14803G>T p.G4935* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as CM098906, COSV100772044; called by muse, mutect2, varscan2
- SAAL1 | c.1397del p.N466Tfs*5 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs766727085; called by mutect2, pindel, varscan2
- SCO1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99703584; called by muse, mutect2
- SCUBE3 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1249043061, COSV51455757, COSV99234911; called by muse, mutect2, varscan2
- SDK2 | c.4792C>T p.R1598W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs865895593, COSV66186335; called by muse, mutect2, varscan2
- SEC61A1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV54576876; called by muse, mutect2, varscan2
- SEC63 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754604388, COSV100938443; called by muse, mutect2, varscan2
- SEMA3C | c.1486-2A>C p.X496_splice | Splice Site (SNP) | VAF 33/76 reads (43%) | catalogued as COSV99543478; called by muse, mutect2, varscan2
- SEMA5B | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs368408333, COSV99531009; called by muse, varscan2
- SEMA6A | c.32C>A p.T11K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs1356673527, COSV99963547; called by muse, mutect2, varscan2
- SENP3 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV99547916; called by muse, mutect2, varscan2
- SERGEF | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99787564; called by muse, mutect2, varscan2
- SEZ6 | c.915dup p.P306Afs*2 | Frame Shift Ins (INS) | VAF 30/86 reads (35%) | catalogued as rs766332422; called by mutect2, varscan2
- SFRP5 | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV99823233; called by muse, mutect2
- SH3PXD2A | c.1265C>T p.P422L (on ENST00000369774 / NM_001365079.1; = p.P394L on NM_014631.2) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs755348691, COSV60116381; called by muse, mutect2, varscan2
- SHANK3 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.964); catalogued as rs748945187, COSV99437489; called by muse, mutect2, varscan2
- SHF | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as COSV99334657; called by muse, mutect2, varscan2
- SHLD2 | c.115dup p.I39Nfs*15 | Frame Shift Ins (INS) | VAF 41/106 reads (39%) | catalogued as rs750856045; called by mutect2, varscan2
- SIGLEC5 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773993688, COSV55784848; called by muse, mutect2, varscan2
- SIPA1L1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100665816; called by muse, mutect2, varscan2
- SLAIN2 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV99971770; called by muse, mutect2, varscan2
- SLC12A4 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.91); PolyPhen benign (0.037); catalogued as rs766407665, COSV99863175; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 37/116 reads (32%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC22A2 | c.519-2A>G p.X173_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100871014; called by muse, varscan2
- SLC23A2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs770025145, COSV100595150; called by muse, mutect2, varscan2
- SLC25A31 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs533689186, COSV99829533; called by muse, mutect2
- SLC26A2 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53826098; called by muse, mutect2, varscan2
- SLC26A7 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs200934477, COSV52592539, COSV99404314; called by muse, mutect2, varscan2
- SLC2A12 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs369266906; called by muse, mutect2, varscan2
- SLC35G3 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.994); catalogued as COSV99268988; called by muse, mutect2, varscan2
- SLC37A3 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as rs573227005, COSV58265365; called by muse, mutect2, varscan2
- SLC39A11 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs150469370; called by muse, mutect2, varscan2
- SLC47A2 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs751597777, COSV100328164; called by muse, mutect2, varscan2
- SLC52A2 | c.1036G>T p.G346C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100095944; called by muse, mutect2, varscan2
- SLC9A6 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV100857928; called by muse, mutect2, varscan2
- SLC9A8 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs558250277, COSV64287424; called by muse, mutect2, varscan2
- SLCO4A1 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs753253895, COSV99414951; called by muse, mutect2, varscan2
- SLIT3 | c.3503A>G p.Y1168C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100268899; called by muse, mutect2
- SLIT3 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1313460054, COSV100268900; called by muse, mutect2, varscan2
- SLITRK5 | c.1835G>A p.C612Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100280272, COSV100280380, COSV61525965; called by muse, mutect2, varscan2
- SMAD4 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100748076, COSV61684586; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as rs760667210; called by mutect2, varscan2
- SMPD3 | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV54716603; called by muse, mutect2, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs758895137; called by mutect2, varscan2
- SNTG2 | c.1113C>A p.N371K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100423782; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs768873484; called by mutect2, varscan2
- SORD | c.1039A>G p.M347V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV99980740; called by muse, mutect2, varscan2
- SP6 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1218388854, COSV100647068; called by muse, mutect2, varscan2
- SPATC1 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV101085175; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 34/60 reads (57%) | catalogued as rs750890082; called by mutect2, varscan2
- SPEF2 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.058); catalogued as COSV100608199, COSV99054795; called by muse, mutect2, varscan2
- SPRED3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100612755; called by muse, mutect2, varscan2
- SPRY2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV101001727; called by muse, mutect2, varscan2
- STAC3 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100234665; called by muse, mutect2, varscan2
- STK32B | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs769500569, COSV51475281, COSV99286320; called by muse, mutect2, varscan2
- STK36 | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1394418102, COSV99831708; called by muse, mutect2, varscan2
- STN1 | c.441T>G p.I147M | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99830275; called by muse, mutect2, varscan2
- STON2 | c.1268C>T p.A423V (on ENST00000649389 / NM_001366849.2; = p.A366V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV99964984; called by muse, mutect2, varscan2
- STRIP2 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as rs367686911; called by muse, mutect2, varscan2
- SYCP2 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs940666597, COSV100698375; called by muse, mutect2, varscan2
- SYK | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773478505, COSV65328614; called by muse, varscan2
- SYMPK | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs977583970, COSV99841922; called by muse, mutect2
- SYNM | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs547315336, COSV60371263; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- SYTL3 | c.844G>T p.G282C (on ENST00000611299 / NM_001242394.1; = p.G214C on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99792293; called by muse, mutect2, varscan2
- SZT2 | c.9563G>A p.R3188Q (on ENST00000634258 / NM_001365999.1; = p.R3131Q on NM_015284.4) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1297464117, COSV100981317, COSV65095228; called by muse, mutect2, varscan2
- TAFA5 | c.206C>T p.A69V (on ENST00000402357 / NM_001082967.3; = p.A62V on NM_015381.7) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs929430715, COSV60981425; called by muse, mutect2, varscan2
- TAP2 | c.1399del p.V467Lfs*2 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as COSV100886875; called by mutect2, pindel, varscan2
- TAT | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs767941301, COSV100587699; called by muse, mutect2, varscan2
- TBC1D17 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs756084780, COSV55578199; called by muse, mutect2
- TBCEL | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV99412319; called by muse, mutect2, varscan2
- TBKBP1 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64653742; called by muse, mutect2, varscan2
- TCERG1 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1240786345, COSV57036089, COSV57040026; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as rs751224053; called by mutect2, pindel, varscan2
- TCF20 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); catalogued as rs781682890, COSV59489789; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs745872748; called by mutect2, varscan2
- TDG | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV99904285; called by muse, mutect2, varscan2
- TENM3 | c.6511A>G p.T2171A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101305302; called by mutect2, varscan2
- TENM4 | c.6110C>T p.T2037M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs370873891; called by muse, mutect2, varscan2
- TENM4 | c.5870C>T p.T1957M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774521396, COSV53684513; called by muse, mutect2, varscan2
- TEX29 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as rs199521485, COSV99366136; called by muse, mutect2, varscan2
- TFIP11 | c.1882del p.H628Tfs*11 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs749918134; called by mutect2, pindel, varscan2
- TGFBR3 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.154); catalogued as COSV99283445; called by muse, mutect2, varscan2
- TGFBR3 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV99283447; called by muse, mutect2
- THBS2 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.488); catalogued as rs772559879, COSV64677376; called by muse, mutect2, varscan2
- TLCD4 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774641830, COSV64631580; called by muse, mutect2, varscan2
- TMC3 | c.2486C>T p.T829I | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.168); catalogued as rs745790608, COSV100845968; called by muse, mutect2, varscan2
- TMCC2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319469; called by muse, mutect2, varscan2
- TMEM11 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV100471879, COSV100471976; called by muse, mutect2, varscan2
- TMEM131 | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs766131305, COSV99488773, COSV99488893; called by muse, mutect2, varscan2
- TMEM204 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.862); catalogued as rs1363116645, COSV99560104; called by muse, mutect2, varscan2
- TMEM222 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs551763083, COSV100929992; called by muse, mutect2, varscan2
- TMEM266 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.142); catalogued as rs556150508, COSV66379890; called by muse, mutect2, varscan2
- TMPO | c.295dup p.T99Nfs*2 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs770800449; called by mutect2, varscan2
- TNFRSF10B | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 53/169 reads (31%) | catalogued as rs760766067, COSV99311154; called by muse, mutect2, varscan2
- TNS2 | c.1351G>A p.V451M (on ENST00000314250 / NM_170754.4; = p.V461M on NM_015319.2) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs372106986; called by muse, mutect2, varscan2
- TNS2 | c.2755C>T p.Q919* (on ENST00000314250 / NM_170754.4; = p.Q929* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV100036835; called by muse, mutect2, varscan2
- TOE1 | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV100517572; called by muse, mutect2, varscan2
- TOP1MT | c.157T>C p.W53R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239588; called by muse, mutect2, varscan2
- TP53 | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV53135423; called by muse, mutect2, varscan2
- TP53BP2 | c.3317C>T p.A1106V (on ENST00000343537 / NM_001031685.3; = p.A977V on NM_005426.2) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs753930874, COSV59067395; called by muse, mutect2, varscan2
- TP53BP2 | c.275dup p.G93Wfs*25 | Frame Shift Ins (INS) | VAF 9/31 reads (29%) | catalogued as rs1206100374; called by mutect2, pindel, varscan2
- TPGS2 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs755462731, COSV100528697; called by muse, mutect2, varscan2
- TRAPPC10 | c.2728A>G p.K910E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV99378965; called by muse, mutect2, varscan2
- TRIM23 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.429); catalogued as COSV99140139; called by muse, mutect2, varscan2
- TRIM39 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.229); catalogued as COSV100935868; called by muse, mutect2, varscan2
- TRIM49 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316176; called by muse, mutect2, varscan2
- TRMT1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1227547282, COSV99457050; called by muse, mutect2, varscan2
- TRPA1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100084788; called by muse, mutect2, varscan2
- TRPM4 | c.2764A>G p.I922V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99420537; called by muse, mutect2, varscan2
- TRPM8 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs897159839, COSV61225258; called by muse, mutect2, varscan2
- TSSK1B | c.900del p.E301Nfs*101 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as COSV101180989, COSV66816083; called by mutect2, pindel, varscan2
- TTC3 | c.4692del p.E1565Kfs*6 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs778730652; called by mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs768996038, COSV57882295; called by pindel, varscan2
- TUFM | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767938338, COSV100493020; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs760251146; called by mutect2, varscan2
- TYRP1 | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101141410; called by muse, mutect2, varscan2
- U2AF2 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99069159; called by muse, mutect2, varscan2
- UBA1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1208061610, COSV100255934; called by muse, mutect2, varscan2
- UBE2D1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs766515311, COSV64218162; called by muse, mutect2, varscan2
- UBQLN2 | c.1300C>A p.L434M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV100592768; called by muse, mutect2, varscan2
- UGT1A4 | c.517del p.W173Gfs*8 | Frame Shift Del (DEL) | VAF 51/159 reads (32%) | catalogued as rs780658532; called by mutect2, pindel, varscan2
- UGT1A8 | c.677del p.N226Mfs*3 | Frame Shift Del (DEL) | VAF 40/131 reads (31%) | catalogued as rs751079138; called by mutect2, pindel, varscan2
- ULK2 | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs557671381, COSV64445422; called by muse, mutect2, varscan2
- UNC13B | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541221911, COSV65931696; called by muse, mutect2, varscan2
- USO1 | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as rs371639359; called by muse, mutect2, varscan2
- USP24 | c.5902G>A p.A1968T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778750018, COSV99599220; called by muse, mutect2, varscan2
- USP26 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100896708; called by muse, mutect2, varscan2
- USP36 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs372703565; called by muse, mutect2, varscan2
- UTP11 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.047); catalogued as COSV100884963; called by muse, mutect2, varscan2
- UTRN | c.8759A>G p.Q2920R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1345696101, COSV100838692; called by muse, mutect2
- VMP1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99230744; called by muse, mutect2, varscan2
- VPS35L | c.1633del p.Q545Sfs*4 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as COSV51977727; called by mutect2, pindel, varscan2
- VPS51 | c.1550del p.G517Vfs*42 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as COSV99659530; called by mutect2, pindel, varscan2
- VSIG10 | c.1016del p.P339Lfs*7 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs772031843; called by mutect2, pindel, varscan2
- VWF | c.7553G>A p.G2518D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs971026321, COSV99779674; called by muse, mutect2, varscan2
- WDR26 | c.1916G>A p.R639Q (on ENST00000414423 / NM_001379403.1; = p.R539Q on NM_025160.7) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs760399308, COSV54357446; called by muse, mutect2, varscan2
- WDR62 | c.2809G>A p.A937T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99544002; called by muse, mutect2, varscan2
- WDR7 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs754502297, COSV54353613; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNK2 | c.6293G>A p.R2098Q (on ENST00000297954 / NM_001282394.1; = p.R2061Q on NM_006648.3) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424271549, COSV52933024; called by muse, mutect2, varscan2
- WNT8A | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs570741196, COSV64230736; called by muse, mutect2, varscan2
- XPC | c.2419G>A p.V807M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs745660242, COSV53205746; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs762052135; called by mutect2, varscan2
- YIF1B | c.297+1G>A p.X99_splice (on ENST00000339413 / NM_001039673.3; = p.X84_splice on NM_001039671.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as rs772652792, COSV100008019; called by muse, mutect2, varscan2
- YIPF1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs776059115, COSV50777470; called by muse, mutect2, varscan2
- ZBTB21 | c.2756C>T p.T919M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs368359632; called by muse, mutect2, varscan2
- ZBTB4 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100263613; called by muse, mutect2, varscan2
- ZBTB41 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as rs761286798, COSV100962943; called by muse, mutect2, varscan2
- ZBTB48 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs1017427540, COSV100887266; called by muse, mutect2, varscan2
- ZCCHC4 | c.904A>G p.S302G | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100255473; called by muse, mutect2, varscan2
- ZDHHC15 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV100973818; called by muse, mutect2, varscan2
- ZFHX3 | c.2287dup p.E763Gfs*26 | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | catalogued as rs760959844; called by mutect2, varscan2
- ZFP42 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100479060; called by muse, mutect2
- ZMYM3 | c.143del p.P48Lfs*65 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as rs757506048; called by mutect2, pindel, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYND15 | c.2212del p.A738Pfs*8 (on ENST00000433935 / NM_001136046.3; = p.A699Pfs*8 on NM_032265.2) | Frame Shift Del (DEL) | VAF 20/32 reads (63%) | catalogued as rs1567700668; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 33/91 reads (36%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF236 | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765608655, COSV99470829; called by muse, mutect2, varscan2
- ZNF263 | c.1046del p.P349Qfs*45 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs1567252485; called by mutect2, pindel, varscan2
- ZNF345 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100080368; called by muse, mutect2, varscan2
- ZNF350 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs761888276, COSV99702641; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF441 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs765096343, COSV63540914; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF544 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs1429477162, COSV54136727; called by muse, mutect2, varscan2
- ZNF598 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs767343182, COSV101461978; called by muse, mutect2, varscan2
- ZNF644 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100494607; called by muse, mutect2, varscan2
- ZNFX1 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100872492; called by muse, mutect2, varscan2
- ZSWIM3 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99666789; called by muse, mutect2, varscan2
- ABCA1 | c.4044del p.F1348Lfs*19 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- ABCC10 | c.3734del p.G1245Afs*22 (on ENST00000372530 / NM_001198934.2; = p.G1217Afs*22 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- ABRA | c.541_543del p.E181del | In Frame Del (DEL) | VAF 34/100 reads (34%) | called by pindel, varscan2
- ABTB2 | c.1900dup p.L634Pfs*44 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- ACADVL | c.887del p.P296Lfs*57 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- ACSM3 | c.918del p.F306Lfs*33 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.2546del p.P849Lfs*69 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- ADGRF4 | c.1940dup p.I648Hfs*31 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.3787_3788del p.M1263Vfs*17 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by pindel, varscan2
- ARAF | c.23del p.P8Lfs*26 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.3350del p.P1117Qfs*15 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- ARHGEF9 | c.1539del p.F514Sfs*16 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | called by pindel, varscan2
- ARID1A | c.6532del p.D2178Tfs*22 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- ARPC5L | c.415_417del p.G139del | In Frame Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- ATP2A1 | c.2804del p.G935Afs*21 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | called by mutect2, varscan2
- BICRAL | c.2689del p.T897Qfs*8 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- BSN | c.1591del p.L531Cfs*11 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- BTBD8 | c.344del p.L115Yfs*11 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- BTNL8 | c.1219del p.I407* | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.1464G>T p.M488I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CACNB2 | c.1935del p.K645Nfs*29 (on ENST00000324631 / NM_201596.3; = p.K590Nfs*29 on NM_000724.4) | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- CANX | c.805_807del p.P269del | In Frame Del (DEL) | VAF 18/40 reads (45%) | called by pindel, varscan2
- CCDC137 | c.495dup p.A166Sfs*9 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, varscan2
- CDC42BPB | c.5101del p.L1701Sfs*60 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- CENPE | c.277dup p.T93Nfs*20 | Frame Shift Ins (INS) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1896del p.M633* | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- CIR1 | c.928_930del p.K310del | In Frame Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- CMYA5 | c.5013del p.G1672Afs*52 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- COL5A2 | c.3254dup p.G1086Wfs*44 | Frame Shift Ins (INS) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
- CSF2RB | c.2660del p.P887Lfs*31 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- CYP4Z1 | c.1509del p.V504Ffs*36 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- DAB2 | c.1638del p.F546Lfs*95 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- DEPDC1 | c.374del p.N125Tfs*3 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- DOCK11 | c.6160dup p.C2054Lfs*4 | Frame Shift Ins (INS) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- DOK1 | c.155del p.G52Vfs*13 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.2214del p.K738Nfs*25 | Frame Shift Del (DEL) | VAF 49/140 reads (35%) | called by mutect2, pindel, varscan2
- ELAVL1 | c.666del p.M223Wfs*6 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- ELF1 | c.1014dup p.G339Rfs*13 | Frame Shift Ins (INS) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 48/86 reads (56%) | called by mutect2, pindel, varscan2
- EPHB1 | c.1326dup p.V443Sfs*26 | Frame Shift Ins (INS) | VAF 29/103 reads (28%) | called by mutect2, pindel, varscan2
- EPHB2 | c.3059_3069delinsGGGAATGGG p.K1020Rfs*21 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by pindel, varscan2*
- EPHB6 | c.2126del p.G709Afs*7 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- ERMARD | c.1314del p.K438Nfs*4 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- FAM124B | c.382dup p.V128Gfs*20 | Frame Shift Ins (INS) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- FANCG | c.1410del p.V471Wfs*47 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- FBXO30 | c.1107del p.V370* | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, varscan2
320 further variants in this file (58 protein-altering or splice-affecting, 234 silent, 28 other) are not listed here.
